Somatic mutation profile of tumor specimen 0DIPKZ from CCDI case PBBVWM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Large cell medulloblastoma; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 1.3 years (473 days).
Specimen 0DIPKZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 511c17cf-ef1b-4564-8597-adf6c457e280.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIPKP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1decc7b-76f3-4dfe-aa29-363639e8719f

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C14orf39 | c.1349dup p.F451Vfs*4 | Frame Shift Ins (INS) | VAF 69/540 reads (13%) | catalogued as rs776870689; called by mutect2, varscan2
- LRIT3 | c.1590G>T p.L530F | Missense Mutation (SNP) | VAF 46/445 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- ZNF221 | c.*95G>C | 3'UTR (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
